Somatic mutation profile of tumor specimen 0DUKHI from CCDI case PBCLDU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.3 years (4,475 days).
Specimen 0DUKHI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2799244d-93e9-4f75-b617-05f32bef1e54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUKIQ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a48261de-0545-469c-be22-d32eba126fca

The open-access MAF lists 14 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 2, Silent 2, In Frame Del 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 92/233 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 40/297 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.215C>A p.A72D | Missense Mutation (SNP) | VAF 97/307 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as rs121918454, CM013417, COSV61005613, COSV61008344, COSV61012146; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FTSJ1 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 40/307 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs571791486, COSV50026314; called by muse, mutect2, varscan2
- NF1 | c.3561del p.Q1188Nfs*27 | Frame Shift Del (DEL) | VAF 154/278 reads (55%) | catalogued as CM076339; called by mutect2, pindel, varscan2
- PDGFRA | c.2546A>G p.Y849C | Missense Mutation (SNP) | VAF 16/435 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57267031; called by muse, mutect2
- SPRY4 | c.524C>T p.T175M (on ENST00000434127 / NM_001127496.3; = p.T198M on NM_030964.4) | Missense Mutation (SNP) | VAF 116/287 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs780235494; called by muse, mutect2, varscan2
- TNRC6B | c.3907C>T p.Q1303* (on ENST00000454349 / NM_001162501.2; = p.Q1193* on NM_015088.3) | Nonsense Mutation (SNP) | VAF 52/300 reads (17%) | catalogued as rs1481569128, COSV57295433; called by muse, mutect2, varscan2
- DISC1 | c.648_653del p.L217_G218del | In Frame Del (DEL) | VAF 89/330 reads (27%) | called by mutect2, pindel, varscan2
- KCNB2 | c.1185A>C p.K395N | Missense Mutation (SNP) | VAF 42/363 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HSFX3 | c.330C>T p.I110= | Silent (SNP) | VAF 177/519 reads (34%) | called by muse, mutect2, varscan2
- TUBA3C | c.1227G>T p.V409= | Silent (SNP) | VAF 169/433 reads (39%) | catalogued as rs1238928009, COSV101313835; called by muse, mutect2, varscan2
- RAC3 | c.107+20G>T | Intron (SNP) | VAF 99/254 reads (39%) | called by muse, mutect2, varscan2
- TTC26 | c.1069+3714G>A | Intron (SNP) | VAF 41/110 reads (37%) | catalogued as rs781407732; called by muse, mutect2, varscan2
